Somatic mutation profile of tumor specimen 0DFSSV from CCDI case PBBSIJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Synovial sarcoma, biphasic; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 10.7 years (3,904 days).
Specimen 0DFSSV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63e21c86-0292-4d23-8e33-16324f16aa43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFSS5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ddf70aa-5827-4b4e-b065-a0eb8f9ecbbe

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, 3'UTR 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP002512.3 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 153/276 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs199694619, COSV54405850; called by muse, mutect2, varscan2
- DOCK4 | c.4622C>T p.A1541V | Missense Mutation (SNP) | VAF 30/1049 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV70235000; called by muse, mutect2
- NDST4 | c.2054C>G p.P685R | Missense Mutation (SNP) | VAF 27/818 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV52108382; called by muse, mutect2
- ABCA10 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 241/836 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ELK1 | c.518C>G p.P173R | Missense Mutation (SNP) | VAF 184/847 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- OR2T27 | c.438G>A p.A146= | Silent (SNP) | VAF 205/573 reads (36%) | catalogued as rs766998180; called by muse, mutect2, varscan2
- GGA3 | c.2062-53G>A | Intron (SNP) | VAF 82/132 reads (62%) | catalogued as rs1039865835; called by muse, mutect2, varscan2
- KRT18P66 | n.425G>T | RNA (SNP) | VAF 68/156 reads (44%) | called by muse, mutect2
- UNC5A | c.*7C>A | 3'UTR (SNP) | VAF 257/618 reads (42%) | called by muse, mutect2, varscan2
